Surgical pathology report (de-identified scan), TCGA case TCGA-UW-A72I, project TCGA-KICH (Kidney Chromophobe), tissue source site University of North Carolina, specimen TCGA-UW-A72I-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Case Number :

ICD-O-3
Carcinoma, renal cell
chromophobe type
8317/3
Site O Kidney NOS
C64.9
QW 8/19/13

Diagnosis:

Kidney, left, nephrectomy

Histologic tumor type/subtype: Renal cell carcinoma, chromophobe subtype

Sarcomatoid features: None identified

Histologic grade (if applicable): 3 (of 4)

Tumor size (greatest dimension): 5.0 cm

Tumor focality: Unifocal

Extent of tumor invasion (if present specify if macroscopic or microscopic):

Capsular invasion/perirenal adipose tissue: Not identified

Gerota' s fascia: Not identified

Renal sinus: Not identified

Major veins (renal vein or segmental branches, IVC): Not identified

Ureter: Not identified

Venous (large vessel): Not identified

Lymphatic (small vessel): Not identified

Histologic assessment of surgical margins:

Gerota' s fascia (nephrectomy): Not identified

Renal vein (nephrectomy): Not identified

Ureter (nephrectomy): Not identified

Adrenal gland: Not present in specimen

Lymph nodes: Not identified in specimen

Other significant findings: None

AJCC Staging:

pT1b

pNx

This staging information is based on information available at the time of this report, and is subject to change pending

[page 2 of 3]
clinical review and additional information.

Clinical History:

-year-old female with a left renal mass.

Gross Description:

Specimen fixation: formalin

Type of specimen: radical nephrectomy, left

Side of specimen: left

Size and weight of specimen: 450 grams, 20.0 cm x 11.0 x 5.0 cm

Orientation: The external surface is inked blue.

Presence/absence of adrenal gland: absent

Tumor site: Superior pole involving the cortex grossly

Tumor description: yellow, spongy, well circumscribed

Tumor size: 5.0 x 4.0 x 3.0 cm

Presence/absence of multicentricity: absent

Confinement/non-confinement to the kidney: confined to, but expands but does not break through capsule

Extent of invasion:

Perirenal adipose tissue: does not involve

Gerota' s fascia: does not involve

Renal vein: does not involve

Ureter: does not involve

Renal Sinus: does not involve

Pelvicaliceal: does not involve

Adrenal: not applicable

[page 3 of 3]
Other organs: not applicable

Surgical margins:

Perirenal adipose tissue: negative

Renal vein: negative

Renal artery: negative

Ureter: negative

Description of kidney away from tumor: tan/pink, homogeneous

Hilar lymph nodes: none identified

Other significant findings: The remainder of the kidney is tan, homogeneous without cysts or other lesions. On the upper pole of the kidney directly over the tumor, the capsule is not entirely covered by perirenal fat. This portion of the capsule has been inked blue.

Tissue submitted for normal and tumor

Digital picture: not taken

Block summary:

- A1 - ureter, renal vein and renal artery margins
- A2 - tumor and adjacent parenchyma
- A3 - tumor and adjacent calyces
- A4 - tumor and adjacent blue inked capsule
- A5 - additional representative of tumor and normal parenchyma
- A6 - normal kidney

Source: NCI Genomic Data Commons file d3b5666c-1b0a-4aef-a5ff-62b1436dbc7f (TCGA-UW-A72I.3285CEBB-9022-4875-BD88-77A8B2FEF081.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).